Somatic mutation profile of cancer-model specimen HCM-CSHL-0511-C24-85A (3D Organoid, passage 7; aliquot HCM-CSHL-0511-C24-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0511-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 47.4 years (17,331 days).
Specimen HCM-CSHL-0511-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 374ba738-870d-4c65-a22a-28a8f4b16a97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0511-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0511-C24-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72e17e2b-cea2-4b7d-a45f-f530addefa3a

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 318/328 reads (97%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 521/521 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200512939; called by muse, mutect2, varscan2
- ACSM2A | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 254/268 reads (95%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs752798612; called by muse, mutect2, varscan2
- ACVR2B | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 510/513 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs199622012; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 502/502 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs774699404; called by muse, mutect2, varscan2
- COL6A5 | c.4309G>A p.G1437R | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs12489323, COSV55205665; called by muse, mutect2, varscan2
- EDEM3 | c.2380A>G p.K794E | Missense Mutation (SNP) | VAF 319/319 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs765636238; called by muse, mutect2, varscan2
- FGD2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 252/253 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747641806, COSV51465153; called by muse, mutect2, varscan2
- KCNS3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 578/578 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770320711, COSV58405308; called by muse, varscan2
- LAMA2 | c.7121G>A p.S2374N | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755168390; called by muse, mutect2, varscan2
- MKX | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748997066, COSV65393548; called by muse, mutect2, varscan2
- NINL | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 583/583 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1275308034; called by muse, mutect2, varscan2
- RETNLB | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 355/355 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370708969, COSV55465147; called by muse, mutect2, varscan2
- THSD4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 237/684 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV99964157; called by muse, mutect2, varscan2
- TMTC1 | c.508G>A p.V170M (on ENST00000539277 / NM_001193451.2; = p.V62M on NM_175861.3) | Missense Mutation (SNP) | VAF 347/347 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139974018, COSV55490490; called by muse, mutect2, varscan2
- ZNF311 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 673/674 reads (100%) | catalogued as rs751092630; called by muse, mutect2, varscan2
- AC092143.1 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY8 | c.302A>T p.H101L | Missense Mutation (SNP) | VAF 37/960 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- APC2 | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 783/784 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMILIN2 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LRRTM3 | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 30/711 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2
- MAP3K2 | c.1268dup p.C424Lfs*23 | Frame Shift Ins (INS) | VAF 155/216 reads (72%) | called by mutect2, pindel, varscan2
- MUC1 | c.3095_3104del p.L1032Pfs*76 (on ENST00000611571 / NM_001371720.1; = p.L245Pfs*76 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 600/625 reads (96%) | called by mutect2, varscan2
- NKRF | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- NT5DC2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 21/591 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- OXTR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 494/496 reads (100%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFC | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- STK10 | c.1361G>C p.S454T | Missense Mutation (SNP) | VAF 477/478 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- STK11 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 486/486 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANGO6 | c.2879A>C p.H960P | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABHD10 | c.66C>T p.A22= | Silent (SNP) | VAF 853/853 reads (100%) | catalogued as rs768142804; called by muse, mutect2, varscan2
- CER1 | c.315C>T p.F105= | Silent (SNP) | VAF 247/483 reads (51%) | catalogued as COSV101097756; called by muse, mutect2, varscan2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 282/283 reads (100%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- OR52L1 | c.798C>T p.I266= | Silent (SNP) | VAF 48/459 reads (10%) | catalogued as rs1030251666, COSV59988452; called by muse, mutect2, varscan2
- OR5M1 | c.315C>T p.I105= | Silent (SNP) | VAF 434/435 reads (100%) | catalogued as rs755863011, COSV73202247, COSV73202295; called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>T p.S738= | Silent (SNP) | VAF 434/435 reads (100%) | catalogued as COSV50758039, COSV50800092; called by muse, mutect2, varscan2
- POTEB3 | c.372C>T p.D124= | Silent (SNP) | VAF 82/106 reads (77%) | catalogued as rs1197417910; called by mutect2, varscan2
- SPHKAP | c.1770G>A p.P590= | Silent (SNP) | VAF 422/423 reads (100%) | catalogued as rs141688278; called by muse, mutect2, varscan2
- AL031315.1 | c.686-2100G>A | Intron (SNP) | VAF 479/479 reads (100%) | called by muse, mutect2, varscan2
- MAF | c.*4245A>C | 3'UTR (SNP) | VAF 202/202 reads (100%) | catalogued as COSV100391602, COSV58155127; called by muse, mutect2, varscan2
